Somatic mutation profile of tumor specimen TCGA-66-2792-01A (aliquot TCGA-66-2792-01A-01D-0983-08) from TCGA case TCGA-66-2792, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.7 years (21,428 days).
Specimen TCGA-66-2792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45e1e7d0-d19c-4af7-93fe-dc95305be365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2792-11A (Solid Tissue Normal), aliquot TCGA-66-2792-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0854d719-3618-4405-b48a-15feb195f2b4

The open-access MAF lists 149 somatic variants for this specimen: 113 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Nonsense Mutation 8, In Frame Del 3, RNA 2, Splice Site 2, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/13 reads (85%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ABCC8 | c.3320C>A p.A1107D | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1159111737, COSV56846023, COSV56848532; called by muse, mutect2, varscan2
- ADAMTS12 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61255281, COSV61270239; called by muse, mutect2, varscan2
- AKR1E2 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV53629601; called by muse, mutect2, varscan2
- ANKAR | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55609337; called by muse, mutect2, varscan2
- ANKRD13C | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); catalogued as COSV52029046; called by muse, mutect2, varscan2
- AP3D1 | c.220T>A p.W74R | Missense Mutation (SNP) | VAF 123/154 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61424412; called by muse, mutect2, varscan2
- ARID4A | c.1144T>G p.S382A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV62161938; called by muse, mutect2, varscan2
- ATP1B2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV51514718; called by muse, mutect2, varscan2
- C5 | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56323783; called by muse, mutect2, varscan2
- CDC42EP1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1257159070, COSV50755598; called by muse, mutect2, varscan2
- CEACAM6 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as COSV52266397; called by muse, mutect2, varscan2
- CFAP47 | c.1276A>C p.M426L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as COSV52880489; called by muse, mutect2, varscan2
- CLCNKA | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV58890365; called by muse, mutect2, varscan2
- COL4A5 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV60355924; called by muse, mutect2, varscan2
- CSNK1G1 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100274312, COSV57306640; called by muse, mutect2, varscan2
- DEAF1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1564949612, COSV58605718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.622); catalogued as COSV53820082; called by muse, mutect2, varscan2
- DNAH9 | c.1518G>C p.T506= | Splice Region (SNP) | VAF 15/70 reads (21%) | catalogued as COSV52333509, COSV52336611; called by muse, mutect2, varscan2
- EDAR | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs757595565, COSV51499780; called by muse, mutect2, varscan2
- ERCC6 | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV63387814; called by muse, mutect2, varscan2
- ERV3-1 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99275307; called by muse, mutect2, varscan2
- EXOC5 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1212087876, COSV61770094; called by muse, mutect2, varscan2
- FAAP100 | c.1685C>G p.A562G | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV59883881; called by muse, mutect2, varscan2
- FAM234B | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52192420; called by muse, mutect2, varscan2
- FMN2 | c.2261T>G p.V754G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV60416531; called by muse, mutect2, varscan2
- FSCB | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV61216484; called by muse, mutect2, varscan2
- FSCB | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV100469805, COSV61216490; called by muse, mutect2, varscan2
- FTMT | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100360151, COSV58419576; called by muse, mutect2, varscan2
- GAK | c.455_457del p.F152del | In Frame Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs749675553; called by pindel, varscan2
- GANAB | c.1620G>A p.W540* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV60461713; called by muse, mutect2, varscan2
- GET3 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV62001815; called by muse, mutect2, varscan2
- GREB1 | c.1595T>C p.M532T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.21); catalogued as COSV52180294; called by muse, mutect2, varscan2
- HAVCR1 | c.147A>C p.R49S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59397621; called by muse, mutect2, varscan2
- HSPBAP1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53745337, COSV53749661; called by muse, mutect2, varscan2
- JDP2 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.838); catalogued as rs1293829582, COSV50867631; called by muse, varscan2
- KCNJ16 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52250594; called by muse, mutect2, varscan2
- KCNS2 | c.1287C>A p.S429R | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV54637136; called by muse, mutect2, varscan2
- KLHL38 | c.1346T>A p.I449N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV58085977; called by muse, mutect2, varscan2
- KRTAP6-2 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | PolyPhen probably damaging (0.934); catalogued as COSV58181884; called by muse, mutect2, varscan2
- LAMC3 | c.4189_4191del p.K1397del | In Frame Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs755505326; called by pindel, varscan2
- LAS1L | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56706317; called by muse, mutect2, varscan2
- LGI2 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs762820735, COSV66122287; called by muse, mutect2, varscan2
- LIMK2 | c.1901G>T p.R634L | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV53222936; called by muse, mutect2, varscan2
- LRP1B | c.11026G>T p.A3676S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.055); catalogued as COSV67185302; called by muse, mutect2, varscan2
- MAN2A1 | c.2746G>T p.V916F | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54846154; called by muse, mutect2, varscan2
- MAP4K1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV50263696; called by muse, mutect2, varscan2
- MATN2 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706478; called by muse, mutect2, varscan2
- MEF2D | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61726716; called by muse, mutect2, varscan2
- MGAT5B | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1249336895, COSV56924855; called by muse, mutect2, varscan2
- MKRN1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1482074668, COSV55435862; called by muse, mutect2, varscan2
- MYH1 | c.4491C>A p.D1497E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.152); catalogued as COSV56843482; called by muse, mutect2, varscan2
- NAV2 | c.2795C>T p.T932I (on ENST00000396087 / NM_001244963.2; = p.T909I on NM_145117.5) | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.654); catalogued as rs1490068462, COSV62315023; called by muse, mutect2, varscan2
- NFKB1 | c.405-1G>T p.X135_splice (on ENST00000394820 / NM_001382627.1; = p.X136_splice on NM_003998.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 45/66 reads (68%) | catalogued as COSV56954385; called by muse, mutect2, varscan2
- NOVA1 | c.995T>A p.L332* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV57472178; called by muse, mutect2, varscan2
- NOX1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as COSV54193262; called by muse, mutect2, varscan2
- NPFFR2 | c.867A>C p.E289D | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV58146191; called by muse, mutect2, varscan2
- NRIP3 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV58468814; called by muse, mutect2, varscan2
- OR12D3 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs762953611, COSV65826286; called by muse, mutect2, varscan2
- OR13C4 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52925783; called by muse, mutect2, varscan2
- OR5M8 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV59115690; called by muse, mutect2, varscan2
- OR9G1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100380404, COSV56447915; called by muse, mutect2
- PARP6 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53002003; called by muse, mutect2, varscan2
- PKHD1L1 | c.8489G>A p.S2830N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs373099174; called by muse, mutect2, varscan2
- PROKR1 | c.953A>T p.K318M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV58136587; called by muse, mutect2, varscan2
- PSKH2 | c.878C>A p.A293E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52609118; called by muse, mutect2, varscan2
- PTPRF | c.4624G>T p.G1542W | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63442438; called by muse, mutect2, varscan2
- RAB30 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52625738; called by muse, mutect2, varscan2
- RASAL2 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs761936330, COSV62709335; called by muse, mutect2, varscan2
- RBM26 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57391094; called by muse, mutect2, varscan2
- RBM6 | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1409693628, COSV56479639; called by muse, mutect2, varscan2
- RBX1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53429581; called by muse, mutect2, varscan2
- REG3G | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as COSV55448162; called by muse, mutect2, varscan2
- RGS12 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV58748648; called by muse, mutect2, varscan2
- RP1 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs112323560, COSV55109816; called by muse, mutect2, varscan2
- RYR2 | c.2245T>A p.L749I | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1482838574, COSV63660690; called by muse, mutect2, varscan2
- SCRIB | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as COSV57582069; called by muse, mutect2, varscan2
- SEPTIN8 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV51523219; called by muse, mutect2, varscan2
- SIK3 | c.2804A>G p.H935R (on ENST00000445177 / NM_001366686.2; = p.H893R on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as rs966391875, COSV52608707; called by muse, mutect2, varscan2
- SLC5A12 | c.800A>T p.K267I | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54818867; called by muse, mutect2, varscan2
- SLURP1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55815872; called by mutect2, varscan2
- SYNE4 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV61010081; called by muse, mutect2, varscan2
- SYTL2 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.661); catalogued as rs1449228772, COSV60355690; called by muse, mutect2, varscan2
- TAOK3 | c.4C>G p.R2G | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66824720; called by muse, mutect2, varscan2
- TCF20 | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV59488179; called by muse, mutect2, varscan2
- TCN1 | c.1023A>T p.R341S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV57252000; called by muse, mutect2, varscan2
- TEX14 | c.2594+2T>C p.X865_splice (on ENST00000240361 / NM_001201457.2; = p.X859_splice on NM_031272.5) | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV53611558; called by muse, mutect2, varscan2
- TGM6 | c.1154C>A p.A385D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52477288; called by muse, mutect2, varscan2
- THAP6 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 35/50 reads (70%) | catalogued as COSV61161788; called by muse, mutect2, varscan2
- TIAM2 | c.5055C>A p.H1685Q (on ENST00000529824; = p.H1656Q on NM_012454.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.78); catalogued as rs753437901, COSV51637601; called by muse, mutect2, varscan2
- TMC7 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV58581456; called by muse, mutect2, varscan2
- TMED8 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53625235; called by muse, mutect2, varscan2
- TNFRSF1A | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.437); catalogued as rs1424748509, COSV50598224; called by muse, mutect2, varscan2
- TRAV22 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs747376259; called by muse, mutect2, varscan2
- TRPM1 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56630298; called by muse, mutect2, varscan2
- TULP4 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV65571920; called by muse, mutect2, varscan2
- UBR5 | c.3662G>T p.C1221F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55279810; called by muse, mutect2, varscan2
- UFSP1 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53814906; called by muse, mutect2, varscan2
- UGT3A2 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 108/146 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV56928300; called by muse, mutect2, varscan2
- USP1 | c.1854G>T p.M618I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51995375; called by muse, mutect2, varscan2
- USP6 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.218); catalogued as COSV51473656, COSV51487729; called by muse, mutect2, varscan2
- ZNF230 | c.1262A>G p.K421R | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV71273223; called by muse, mutect2, varscan2
- ZNF568 | c.932G>C p.C311S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61740426; called by muse, mutect2, varscan2
- ADAMTS15 | c.992del p.G331Afs*44 | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | called by mutect2, pindel, varscan2
- ARAF | c.526del p.L176* | Frame Shift Del (DEL) | VAF 8/11 reads (73%) | called by mutect2, varscan2
- IGHV1OR15-9 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGKV6D-41 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MRC1 | c.3947C>A p.S1316Y | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR6N1 | c.500dup p.F168Ifs*13 | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- SEMA5A | c.1433_1444del p.H478_I482delinsL | In Frame Del (DEL) | VAF 20/124 reads (16%) | called by mutect2, pindel, varscan2
- ACTR3 | c.411A>T p.P137= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV54298229; called by muse, mutect2, varscan2
- BRD2 | c.1971A>G p.L657= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV66372369; called by muse, mutect2, varscan2
- CCKBR | c.714C>T p.Y238= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs555393734, COSV58098518, COSV58099724; called by muse, mutect2, varscan2
- DDX52 | c.387C>T p.S129= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs145856014; called by muse, mutect2, varscan2
- DNAH5 | c.11424A>G p.Q3808= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV54203300; called by muse, mutect2, varscan2
- DUSP10 | c.9G>A p.P3= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs776606563, COSV60456533; called by muse, mutect2, varscan2
- EDRF1 | c.2274T>C p.N758= (on ENST00000356792 / NM_001202438.2; = p.N724= on NM_015608.2) | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV61762347; called by muse, mutect2, varscan2
- EPHA3 | c.1665C>A p.L555= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV60693672; called by muse, mutect2, varscan2
- FAM204A | c.270G>A p.Q90= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV64987544; called by muse, mutect2, varscan2
- FLG2 | c.6495C>T p.S2165= | Silent (SNP) | VAF 44/243 reads (18%) | catalogued as rs1259232599, COSV66166549; called by muse, mutect2, varscan2
- FUT7 | c.747C>A p.G249= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV55797276; called by muse, mutect2, varscan2
- GAL3ST1 | c.468C>T p.N156= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs757856226, COSV58891884; called by muse, mutect2, varscan2
- GAS2L3 | c.324G>A p.V108= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs1362176484, COSV57155985; called by muse, mutect2, varscan2
- GCC1 | c.2209C>T p.L737= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV58461716, COSV58463071; called by muse, mutect2, varscan2
- GLP2R | c.1527T>G p.G509= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV52321805; called by muse, mutect2, varscan2
- LAMA3 | c.4032A>G p.S1344= | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as rs1234747425, COSV58062129; called by muse, mutect2, varscan2
- MATN2 | c.681G>A p.T227= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs761033281, COSV54706460; called by muse, mutect2, varscan2
- MINAR1 | c.567C>G p.A189= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV59580800; called by muse, mutect2, varscan2
- MYH4 | c.2082G>T p.L694= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV55111999; called by muse, mutect2, varscan2
- NPHP3 | c.3891C>G p.L1297= | Silent (SNP) | VAF 68/102 reads (67%) | catalogued as COSV53903900; called by muse, mutect2, varscan2
- OR11L1 | c.357C>A p.A119= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV63313562; called by muse, mutect2, varscan2
- OR2AG1 | c.702G>A p.R234= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs765175046, COSV56625299; called by muse, mutect2, varscan2
- PAN2 | c.2139G>A p.Q713= (on ENST00000425394 / NM_001127460.3; = p.Q709= on NM_014871.5) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57752629; called by mutect2, varscan2
- POM121L12 | c.801C>T p.F267= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as COSV68692193; called by muse, mutect2
- SEMA3C | c.471C>G p.S157= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV54841089; called by muse, mutect2, varscan2
- TBC1D4 | c.345G>A p.A115= | Silent (SNP) | VAF 34/41 reads (83%) | catalogued as COSV66487569; called by muse, mutect2, varscan2
- TEX37 | c.222C>A p.P74= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV57555277; called by muse, mutect2, varscan2
- TMEM159 | c.147G>A p.P49= | Silent (SNP) | VAF 61/84 reads (73%) | catalogued as rs746273804, COSV51785000; called by muse, mutect2, varscan2
- TTC13 | c.2247C>T p.C749= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV64167718; called by muse, mutect2, varscan2
- USP17L2 | c.1239C>G p.P413= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV100414742, COSV61555451; called by muse, mutect2, varscan2
- WDR45B | c.708C>T p.I236= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs756853385, COSV66407756; called by muse, mutect2, varscan2
- XAB2 | c.2259G>A p.T753= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs901531180, COSV50330791; called by muse, mutect2
- ATP2B4 | c.3309+5677C>T | Intron (SNP) | VAF 10/67 reads (15%) | catalogued as rs202010403, COSV58176431; called by muse, mutect2, varscan2
- CCNQP1 | n.398C>A | RNA (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 31/164 reads (19%) | catalogued as rs756590960; called by muse, mutect2, varscan2
- ZNF182 | c.-31A>T | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100429250; called by muse, mutect2
